Somatic mutation profile of tumor specimen MP2PRT-PAVAVX-TBP1-A (aliquot MP2PRT-PAVAVX-TBP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAVAVX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,428 days).
Specimen MP2PRT-PAVAVX-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d70c9013-9c16-4d5a-b888-cd09d811ec89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAVX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAVX-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d887587-9269-4444-ac4a-9490a91a2067

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM7 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51548125; called by muse, mutect2, varscan2
- NEURL2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 23/689 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99509783; called by muse, mutect2
- FOSL2 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 186/559 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GLUD1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 84/696 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH22 | c.705C>T p.R235= | Silent (SNP) | VAF 157/472 reads (33%) | catalogued as rs1304242768, COSV64836497; called by muse, mutect2, varscan2
- DDX28 | c.636C>G p.S212= | Silent (SNP) | VAF 88/547 reads (16%) | called by muse, mutect2, varscan2
- RPA1 | c.924C>T p.L308= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs193035984; called by muse, mutect2
- SPRED3 | chr19:38388804 G>A | 5'Flank (SNP) | VAF 97/351 reads (28%) | called by muse, mutect2, varscan2
